MMRF case MMRF_2058 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/232045ee-86be-4289-bd3d-f1151a5e5863

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.9 years (23,324 days); Days to last known disease status: 966 days (2.6 years); Days to last follow up: 966 days (2.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 191 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 191 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -24 (ECOG 1): M Protein 2.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 8.1 g/dL; Glucose 8.47 mmol/L.
- Day 77 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 8.25 mmol/L.
- Day 140 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 8.25 mmol/L.
- Day 238 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 6.38 mmol/L.
- Day 343 (ECOG 1): M Protein 0.89 g/dL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.7 g/dL; Glucose 7.26 mmol/L.
- Day 427 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.88 mg/dL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 7.3 g/dL; Glucose 7.87 mmol/L.
- Day 602 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.28 mg/dL; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6 mmol/L.
- Day 686 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.02 mg/dL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 1.86 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 777: Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.3 mmol/L; Albumin 42.8 g/L; Total Protein 7.6 g/dL; Glucose 6.77 mmol/L.
- Day 871: Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 3.41 mmol/L.
- Day 966 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day -24: Weight: 75 kg; Height: 175 cm.

Biospecimens (2 samples)
- Sample MMRF_2058_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_2058_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
